Surgical pathology report (de-identified scan), TCGA case TCGA-GU-AATQ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-AATQ-01A (Primary Tumor).

[page 1 of 7]
Results

BIOPSY OR SURGICAL SPECIMEN (Order)

Patient Information

Patient Name

MRN

Sex

DOB

Result Information

Status
Edited

Provider Status
Reviewed

Entry Date

Component Results

Component

Lab

Surgical Pathology

Patient Name
Med Rec #:
Accession #:

ICD O-3
Carcinoma, urothelial NOS 8120/3
Site Bladder wall, NOS C67.9
Op 1/30/14

FINAL PATHOLOGICAL DIAGNOSIS

A. Left distal ureter, radical cystoprostatectomy:

- Unremarkable urothelium; no high grade dysplasia or carcinoma identified
- Frozen section diagnosis is confirmed

B. Right distal ureter, radical cystoprostatectomy:

- Unremarkable urothelium; no high grade dysplasia or carcinoma identified
- Frozen section diagnosis is confirmed

C. Bladder and prostate, radical cystoprostatectomy:

- Invasive urothelial carcinoma with squamous differentiation, high grade
- Tumor invades perivesical tissue macroscopically (pT3b)
- All surgical resection margins free of tumor
- Prostate with benign prostatic hyperplasia; no invasive carcinoma identified
- See CAP template below for full report
- See comment

Per TSS, Squamous differentiation is 40-50%.

D. Right iliac lymph nodes, lymph node dissection:

- Five benign lymph nodes identified, all negative for metastatic carcinoma (0/5)

E. Right obturator lymph nodes, lymph node dissection:

- Three benign lymph nodes identified, all negative for metastatic carcinoma (0/3)

F. Left iliac lymph nodes, lymph node dissection:

- Three benign lymph nodes identified, all negative for metastatic carcinoma (0/3)

G. Left obturator lymph nodes, lymph node dissection:

- Ten benign lymph nodes identified, all negative for metastatic carcinoma (0/10)

CAP Cancer Template
Specimen:

[page 2 of 7]
Bladder
Other (specify): Prostate

Procedure:
Radical cystoprostatectomy

Tumor Site:
Left lateral wall
Anterior wall
Posterior wall
Right ureteral orifice

Tumor Size:
Greatest dimension: 4.5 cm

Histologic Type:
Urothelial (transitional cell) carcinoma with squamous differentiation

Associated Epithelial Lesions:
None identified

Histologic Grade:
Urothelial Carcinoma (WHO 2004/ISUP):
High-grade

Tumor Configuration:
Solid/nodule
Flat
Ulcerated

Microscopic Tumor Extension:
Invades perivesical tissue macroscopically (extravesical mass)

Margins:
Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 0.5 mm
Specify margin: Posterior soft tissue margin

Lymph-Vascular Invasion:
Indeterminate

Pathologic Staging (pTNM):

TNM Descriptors:
m (multiple primary tumors)

Primary Tumor (pT):
pT3b: Macroscopically (extravesicular mass)

Regional Lymph Nodes (pN):
pN0: No lymph node metastasis
Specify: Number examined: 21
Number involved (any size): 0

Distant Metastasis (pM):
Not applicable

Additional Pathologic Findings:
Urothelial dysplasia
Inflammation/regenerative changes

[page 3 of 7]
Ancillary Studies:

None performed at this time; blocks C13 and C14 will be held for future studies if necessary.

The above pathology diagnosis incorporates data elements as outlined in the CAP Cancer Protocols and Checklists which are based on the AJCC/UICC TNM, 7th edition.

DIAGNOSIS COMMENT

Selected slides were reviewed at the _____ on _____, and the diagnoses represent a consensus opinion.

***Electronically Signed Out By _____

CLINICAL HISTORY

Bladder tumor
Radical cystectomy/ prostatectomy with ileal conduit

SPECIMEN(S) RECEIVED

A: Left distal ureter
B: Right distal ureter
C: Bladder and prostate
D: Right iliac lymph nodes
E: Right obturator lymph nodes
F: Left iliac lymph nodes
G: Left obturator lymph nodes

GROSS DESCRIPTION

Specimen A is received fresh for frozen section labeled with the patient's name and designated "left distal ureter". The specimen consists of a segment of ureter measuring 0.6 cm in diameter x 0.3 cm in length.

Section key:

A1 specimen is completely submitted for frozen section

Specimen B is received fresh for frozen section labeled with the patient's name and designated "right distal ureter". The specimen consists of a segment of ureter measuring 0.4 cm in diameter x 0.3 cm in length.

Section key:

B1 specimen is completely submitted for frozen section

Specimen C

Type of specimen: Urinary bladder, ureter stumps, prostate, seminal vesicles

The patient's name and case number on the specimen container match the accompanying paperwork and cassettes.

Procedure: Radical cystoprostatectomy

Fixative: Received fresh and later placed in formalin

Dimensions:

Bladder: Superior to inferior 7.5 cm, right to left 6.0 cm, anterior to posterior 3.5 cm

Right ureter stump: 1.0 cm in length and 0.5 cm in diameter; left 2.5 cm in length and 0.5 cm in diameter

Prostate: Apex to base 3.8 cm, anterior to posterior 3.2 cm, right to left 5.0 cm

Description of findings:

[page 4 of 7]
Tumor: Three distinct separate tumors are identified. The largest tumor occupies the left lateral wall and extends to include portions of both the anterior and posterior wall. In some areas, the tumor appears to abut the inked posterior bladder surface. This tumor measures 4.5 x 3.6 cm. The central portion of the tumor is rough, hemorrhagic, and somewhat shaggy and has a somewhat necrotic appearance. The necrosis involves 80% of the surface of the tumor. There are tan-gray, nodular, viable areas at the peripheral margin of the tumor. On section, this tumor can be seen to deeply invade the bladder wall and appears to have extended through the full thickness to involve the adjacent perivesicular adipose tissue. The second tumor occupies a portion of the posterior wall and extends laterally to surround the right ureteral orifice. This tumor measures 2.5 x 2.0 cm. The tumor is largely exophytic extending 0.9 cm above the lining of the bladder wall. The third tumor occupies a portion of the inferior anterior bladder wall and measures 1.7 x 1.5 cm and rises 0.6 cm above the lining of the bladder wall. The lumen of the bladder contains a large volume of firm friable blood clot. The clot measures 7.0 x 7.0 x 2.5 cm.

Uninvolved mucosa: The involved mucosa has a normal tan-gray appearance with no additional lesions noted. Sectioning through the prostate reveals a normal tan-gray, lobulated, spongy cut surface.

Prostate, seminal vesicles and vasa deferentia:

Ink code:

Anterior: blue

Posterior: black

Right side: orange

Left side: blue

Section key:

- C1 en face urethral resection margins
- C2 largest tumor of left lateral wall, anterior surface
- C3 C8 largest tumor of left lateral wall and posterior surface
- C9, C10 second tumor of right lateral wall
- C11, C12 third tumor anterior wall
- C13 left ureteral orifice
- C14 right ureteral orifice
- C15 right lateral wall
- C16 section of dome
- C17 C19 right prostate submitted distal to proximal
- C20 C22 left prostate submitted distal to proximal
- C23 right seminal vesicle and vas deferens
- C24 left seminal vesicle and vas deferens

Specimen D is received in formalin labeled with the patient's name and designated "right iliac lymph node". The specimen consists of an aggregate of yellow, fatty tissue measuring 5.0 x 4.3 x 2.5 cm. Multiple lymph nodes are identified ranging in size from 0.5 cm up to 2.1 cm in greatest dimension.

Section key: The lymph nodes are entirely submitted as follows:

- D1, D2 largest lymph node trisected
- D3 two lymph nodes, bisected, one marked with ink
- D4 two lymph nodes, bisected, one marked with ink

Specimen E is received in formalin labeled with the patient's name and designated "right obturator lymph node". The specimen consists of an aggregate of yellow, fatty tissue measuring 5.5 x 3.8 x 2.0 cm. Three lymph nodes are identified ranging from 0.8 cm up to 3.5 cm in greatest dimension.

Section key: The lymph nodes are entirely submitted as follows:

- E1 E3 largest lymph node trisected
- E4, E5 one lymph node, bisected
- E6 one single lymph node

Specimen F is received in formalin labeled with the patient's name and designated "left iliac lymph node". The specimen consists of an aggregate of yellow, fatty tissue measuring 3.5 x 2.5 x 1.5 cm. Three lymph nodes are

[page 5 of 7]
identified ranging in size from 0.5 cm up to 1.5 cm in greatest dimension.

Section key:

F1 lymph nodes are completely submitted

Specimen G is received in formalin labeled with the patient's name and designated "left obturator lymph node". The specimen consists of an aggregate of yellow, fatty tissue measuring 4.5 x 4.0 x 2.3 cm. Multiple lymph nodes are identified ranging from 0.2 cm up to 3.0 cm in greatest dimension.

Section key: Lymph nodes are completely submitted as follows:

G1, G2 largest lymph node bisected

G3 two lymph nodes, bisected, one marked with blue ink

G4, G5 multiple single lymph nodes

MICROSCOPIC DESCRIPTION

The stain quality is acceptable.

A-G. The microscopic findings are reflected in the diagnoses rendered.

INTRAOPERATIVE CONSULT DIAGNOSIS

Time in: , Time out:

AFS1, Left distal ureter: "Negative for malignancy"

BFS1, Right distal ureter: "Negative for malignancy"

Conveyed to by on

Interpretation performed at:

Results

Anatomic Pathology Report - Scan on

Result History

BIOPSY OR SURGICAL SPECIMEN

- Order Result History Report.

Transcription

Type ID Author

Anatomic Pathology Report

Signed by

Document Text

Display only: Transcription /

Collection Information

Date and Time

Accession #

Lab Information

[page 6 of 7]
Status:

This order is currently not shared in

Order

BIOPSY OR SURGICAL SPECIMEN

Patient Information

Patient Name

MRN

Sex

DOB

Visit Information

Date

Time

Department
Urology

Provider

Admission Information

Attending Provider

Admitting Provider

Admission Type

Admission Date/Time

Discharge Date

Hospital Service

Auth/Cert Status

Service Area

Unit

Room/Bed

Admission Status
Unknown Status (No Confirmation
Status)

Date and Time

Ordering

Authorizing

Department
Urology

Order

Order Name

BIOPSY OR SURGICAL SPECIMEN

Code

Order Number

Discharge Information

Discharge Provider
(none)

Date/Time
(none)

Disposition
(none)

Destination
(none)

Order Providers

Authorizing Provider

Encounter Provider

Results

Anatomic Pathology Report - Scan

Collection Information

Date and Time

Accession #

Priority and Order Details

[page 7 of 7]
Priority
Routine

Class

[REDACTED]

Source: NCI Genomic Data Commons file e8ff172a-6bc0-4142-aef0-c050422dae9b (TCGA-GU-AATQ.FF69B05C-B041-4CBA-A481-66AB2510A4AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).